Somatic mutation profile of tumor specimen TCGA-78-7158-01A (aliquot TCGA-78-7158-01A-11D-2036-08) from TCGA case TCGA-78-7158, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.5 years (21,742 days).
Specimen TCGA-78-7158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 563682fe-a266-4e32-85cd-1c785856892f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7158-10A (Blood Derived Normal), aliquot TCGA-78-7158-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dc8cf06-98c7-4552-b64d-80304abc70de

The open-access MAF lists 258 somatic variants for this specimen: 200 protein-altering or splice-affecting, 52 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 52, Nonsense Mutation 15, Frame Shift Del 9, Splice Site 6, Intron 4, Splice Region 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1861G>T p.D621Y | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55113124, COSV55117127; called by muse, mutect2, varscan2
- ABCA13 | c.12003G>T p.E4001D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71283037; called by muse, mutect2, varscan2
- ABCB1 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV55944690, COSV55946090; called by muse, mutect2, varscan2
- ABCC12 | c.3451G>A p.G1151R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774085761, COSV60911379; called by muse, mutect2, varscan2
- ADAM19 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV57422468; called by muse, mutect2, varscan2
- ADAMTS12 | c.3047C>A p.P1016Q | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61255008; called by muse, mutect2, varscan2
- AFF2 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60654004; called by muse, mutect2
- ALS2CL | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59670016; called by muse, mutect2, varscan2
- ALX1 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV57491034; called by muse, mutect2, varscan2
- AMELX | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV61623691; called by muse, mutect2, varscan2
- ASB5 | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.966); catalogued as COSV56668379; called by muse, mutect2
- BMP6 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); catalogued as COSV51660380; called by muse, mutect2, varscan2
- BRWD3 | c.4829G>T p.G1610V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); catalogued as COSV64743656; called by muse, mutect2, varscan2
- C10orf71 | c.284G>T p.W95L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60504174, COSV60508433; called by muse, mutect2, varscan2
- CA10 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as rs777074047, COSV53336786; called by muse, mutect2, varscan2
- CACNA1E | c.3775G>T p.V1259L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62381481; called by muse, mutect2, varscan2
- CALN1 | c.103G>A p.V35M (on ENST00000329008 / NM_001017440.3; = p.V77M on NM_031468.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs753021517, COSV61121482; called by muse, mutect2, varscan2
- CARMIL1 | c.3130A>T p.T1044S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61513378, COSV61514925; called by muse, mutect2, varscan2
- CCBE1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765432175, COSV67949046; called by muse, mutect2, varscan2
- CDH12 | c.1344C>A p.D448E | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66386967; called by muse, mutect2, varscan2
- CDKAL1 | c.1248G>C p.R416S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51179592; called by muse, mutect2, varscan2
- CEP164 | c.1686G>T p.K562N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as COSV54037966; called by muse, mutect2, varscan2
- CEP350 | c.3646A>C p.S1216R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV62598627; called by muse, mutect2, varscan2
- CFAP44 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55608371; called by muse, mutect2, varscan2
- CHD7 | c.3884T>A p.I1295N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV71106965; called by muse, mutect2, varscan2
- CHL1 | c.2705C>T p.P902L (on ENST00000397491 / NM_001253387.1; = p.P918L on NM_006614.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56585902, COSV56595937; called by muse, mutect2, varscan2
- CKAP2L | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56695538; called by muse, mutect2
- CLCN1 | c.1220C>A p.P407Q | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367238; called by muse, mutect2, varscan2
- CLEC16A | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755356205, COSV68497704; called by muse, mutect2, varscan2
- CLUH | c.3262G>T p.A1088S (on ENST00000435359; = p.A1127S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs747122833, COSV101425659, COSV70927633; called by muse, mutect2, varscan2
- CNGA2 | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61703008; called by muse, mutect2, varscan2
- CNTN4 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV68561748; called by muse, mutect2, varscan2
- COL15A1 | c.723G>A p.S241= | Splice Region (SNP) | VAF 49/106 reads (46%) | catalogued as rs199838728; called by muse, mutect2, varscan2
- COL5A3 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1251072101, COSV53405852; called by muse, mutect2, varscan2
- CPS1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51801306; called by muse, mutect2, varscan2
- CREBBP | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52113316; called by muse, mutect2, varscan2
- CRNN | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55120657; called by muse, mutect2
- CSMD1 | c.9836C>A p.P3279Q (on ENST00000520002; = p.P3278Q on NM_033225.6) | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59279026; called by muse, mutect2, varscan2
- CSMD1 | c.6108C>A p.Y2036* (on ENST00000520002; = p.Y2035* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 69/119 reads (58%) | catalogued as COSV59279054; called by muse, mutect2, varscan2
- CTC1 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV59851937; called by muse, mutect2, varscan2
- CYLD | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV61092799; called by muse, mutect2, varscan2
- CYP4X1 | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV64149575, COSV64150772; called by muse, mutect2
- DAGLA | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV57193778, COSV57197770; called by muse, mutect2, varscan2
- DCLK3 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV69362133; called by muse, mutect2, varscan2
- DDI1 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100159440, COSV56367827; called by muse, mutect2, varscan2
- DENND1A | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as COSV65346903; called by muse, mutect2
- DGKD | c.3286G>T p.A1096S (on ENST00000264057 / NM_152879.3; = p.A1052S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs751257815, COSV51032869; called by muse, mutect2, varscan2
- DISP1 | c.3867G>T p.Q1289H | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52654338; called by muse, mutect2, varscan2
- DPY19L1 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV60580619, COSV60584213; called by muse, mutect2, varscan2
- DPYSL3 | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58323752; called by muse, mutect2, varscan2
- DSCAML1 | c.1957G>T p.V653F (on ENST00000321322; = p.V593F on NM_020693.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV58380717; called by muse, mutect2, varscan2
- DUSP26 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56360631; called by muse, mutect2, varscan2
- DUSP9 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61437776; called by muse, mutect2, varscan2
- EDEM1 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV56580783; called by muse, mutect2, varscan2
- EGFR | c.2719T>A p.L907M | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1218871031, COSV51768921; called by muse, mutect2, varscan2
- ELF1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53496806; called by muse, mutect2, varscan2
- EMX2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV71294357; called by muse, mutect2, varscan2
- EXO1 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as COSV62216200; called by muse, mutect2
- EXT2 | c.1789G>A p.A597T (on ENST00000343631; = p.A630T on NM_000401.3) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436423139, COSV59146508; called by muse, mutect2, varscan2
- FAM13C | c.536A>T p.K179M | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53242747; called by muse, mutect2, varscan2
- FARS2 | c.1185G>C p.K395N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV51164391; called by muse, mutect2, varscan2
- FBN3 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV54452729; called by muse, mutect2, varscan2
- FGF12 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV53151217; called by muse, mutect2, varscan2
- FNIP1 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as COSV57193616; called by muse, mutect2
- FZD8 | c.176A>T p.H59L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV65967485; called by muse, mutect2, varscan2
- GABRA4 | c.205+2T>A p.X69_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV51922054; called by muse, mutect2, varscan2
- GMEB2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs752805008, COSV56607678; called by muse, mutect2, varscan2
- GPSM2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CD124876, COSV51440952; called by muse, mutect2, varscan2
- ICE1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV56818684; called by muse, mutect2, varscan2
- IGSF21 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs201284891, COSV52124955, COSV99246413; called by muse, mutect2, varscan2
- INSC | c.1511C>G p.A504G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65408658; called by muse, mutect2, varscan2
- INTS2 | c.1866G>T p.Q622H | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV52150766; called by muse, mutect2, varscan2
- ITGA8 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1186611447, COSV65224162; called by muse, mutect2, varscan2
- ITGB6 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs751132914, COSV51790647, COSV99325115; called by muse, mutect2
- KANSL1L | c.397A>T p.I133F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1384165089, COSV55989307; called by muse, mutect2, varscan2
- KCNJ16 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as rs772746245, COSV52250487, COSV52251504; called by muse, mutect2, varscan2
- KCNK6 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV54578775; called by muse, mutect2, varscan2
- KEAP1 | c.1381A>G p.I461V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.484); catalogued as COSV50260791, COSV50349793; called by muse, mutect2
- KIAA1755 | c.3377C>A p.P1126Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54073425, COSV54077773; called by muse, mutect2, varscan2
- KIAA2026 | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV67353172; called by muse, mutect2, varscan2
- KIF1A | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs766693472, COSV57482188; called by mutect2, varscan2
- KPRP | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV64220900; called by muse, mutect2, varscan2
- LAMC2 | c.3423G>T p.M1141I | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51452182; called by muse, mutect2, varscan2
- LGALS2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as rs763088523, COSV50755577, COSV50760238; called by muse, mutect2, varscan2
- LRSAM1 | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV55938152; called by muse, mutect2, varscan2
- MAGEA4 | c.546C>A p.C182* | Nonsense Mutation (SNP) | VAF 69/163 reads (42%) | catalogued as COSV52340137; called by muse, mutect2, varscan2
- METTL17 | c.529-1G>A p.X177_splice | Splice Site (SNP) | VAF 52/122 reads (43%) | catalogued as COSV59554959; called by muse, mutect2, varscan2
- MMP11 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53155349; called by muse, mutect2, varscan2
- MMUT | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV51272257; called by muse, mutect2, varscan2
- MOSPD2 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66859593; called by muse, mutect2, varscan2
- MRPL10 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV50106506; called by muse, mutect2, varscan2
- MYH1 | c.1070G>C p.G357A | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV56843302; called by muse, mutect2, varscan2
- MYH7 | c.4512C>A p.N1504K | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV62516047; called by muse, mutect2, varscan2
- NCAN | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53046405; called by muse, mutect2, varscan2
- NFYC | c.773C>G p.S258* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV58125605; called by muse, mutect2, varscan2
- NKRF | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV58660562; called by muse, mutect2, varscan2
- NLRP12 | c.3011A>T p.Y1004F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.535); catalogued as COSV60743348; called by muse, mutect2, varscan2
- NLRP4 | c.2035T>G p.F679V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV56707397; called by muse, mutect2, varscan2
- NSUN2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV52952325; called by muse, mutect2
- NTRK3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58107892; called by muse, mutect2, varscan2
- NTRK3 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV58107916; called by muse, mutect2, varscan2
- NUP210L | c.5046G>T p.K1682N | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV55141069, COSV55159084; called by muse, mutect2, varscan2
- OPN1SW | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50821200; called by muse, mutect2, varscan2
- OR14K1 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 83/396 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV99315096; called by muse, mutect2, varscan2
- OR52E4 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV57623736, COSV57624377; called by muse, mutect2, varscan2
- OR52R1 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61887254; called by muse, mutect2, varscan2
- OR6Y1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56928070, COSV56928209; called by muse, mutect2, varscan2
- OVCH1 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.447); catalogued as COSV58959227; called by muse, varscan2
- P4HA2 | c.998G>C p.W333S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV51323669; called by muse, mutect2, varscan2
- PCDH12 | c.2205G>C p.L735F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51518972; called by muse, mutect2, varscan2
- PCDHA4 | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 60/129 reads (47%) | catalogued as COSV63538670, COSV63538981; called by muse, mutect2, varscan2
- PDIA2 | c.827T>A p.L276H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV51982993; called by muse, mutect2, varscan2
- PHACTR3 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV63025046; called by muse, mutect2, varscan2
- PLCB1 | c.1192T>A p.C398S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV62037170; called by muse, mutect2, varscan2
- PLXDC2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.726); catalogued as rs1281432850, COSV65900562; called by muse, mutect2, varscan2
- PMS2 | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV56219489; called by mutect2, varscan2
- PNMA5 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62625315; called by muse, mutect2, varscan2
- POPDC3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as rs755953856, COSV54643025, COSV54644710; called by muse, mutect2, varscan2
- POU3F4 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.142); catalogued as COSV100937307, COSV64537662; called by muse, mutect2, varscan2
- PPP1R3A | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV52875600; called by muse, mutect2, varscan2
- PTGS1 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV56290024; called by muse, mutect2, varscan2
- PVALB | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53411822; called by muse, mutect2, varscan2
- RAB11FIP5 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV50247764; called by muse, varscan2
- RAB11FIP5 | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 26/186 reads (14%) | catalogued as COSV50247772; called by muse, varscan2
- RAB8B | c.123C>T p.I41= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as rs749381235, COSV58488926; called by mutect2, varscan2
- RAD21 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52056080; called by muse, mutect2, varscan2
- RBM10 | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV61307730; called by muse, mutect2, varscan2
- RBM45 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.15); catalogued as COSV53719884; called by muse, mutect2, varscan2
- REG3G | c.122C>G p.P41R | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55447804, COSV55449729; called by muse, varscan2
- RGS10 | c.167G>C p.S56T (on ENST00000369101; = p.S50T on NM_002925.3) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV64861417; called by muse, mutect2, varscan2
- RIBC1 | c.664-2A>G p.X222_splice | Splice Site (SNP) | VAF 12/23 reads (52%) | catalogued as COSV51447406; called by muse, mutect2, varscan2
- RTF2 | c.742+1G>T p.X248_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV50127721; called by muse, mutect2, varscan2
- SCN3A | c.4853C>A p.T1618N | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51800783, COSV51830029; called by muse, mutect2, varscan2
- SEC24B | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as COSV54495099; called by mutect2, varscan2
- SEMA3C | c.659-2A>G p.X220_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | catalogued as COSV54840954; called by muse, mutect2, varscan2
- SHOC1 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59497336; called by muse, mutect2
- SLC17A6 | c.1514G>T p.W505L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54133328, COSV54136526; called by muse, mutect2, varscan2
- SLC22A7 | c.1345G>T p.A449S (on ENST00000372585 / NM_153320.2; = p.A447S on NM_006672.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV51482622; called by muse, mutect2, varscan2
- SLC25A18 | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376253175, COSV59407564; called by muse, mutect2, varscan2
- SLC4A11 | c.1706C>G p.S569* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as CD070527, COSV66260192; called by muse, mutect2
- SORCS3 | c.3345G>C p.L1115F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100865067, COSV63802118; called by muse, mutect2
- SOX1 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV58378249; called by mutect2, varscan2
- SOX3 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV65167859; called by muse, varscan2
- STEAP1 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV51880854, COSV99787561; called by muse, mutect2, varscan2
- TAF1L | c.2112G>T p.E704D | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644727; called by muse, mutect2, varscan2
- TAS1R2 | c.1189C>A p.H397N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV64743483; called by muse, mutect2, varscan2
- TBC1D25 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV65123174, COSV65123323; called by muse, mutect2, varscan2
- TCF20 | c.2908G>T p.A970S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV59488056; called by muse, mutect2, varscan2
- TCHH | c.5733del p.L1912Ffs*34 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as COSV64273445; called by mutect2, pindel, varscan2
- TEX13B | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV57202061; called by muse, mutect2, varscan2
- TGFB1I1 | c.430C>G p.P144A (on ENST00000394863 / NM_001042454.3; = p.P127A on NM_015927.4) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV62357130; called by muse, mutect2, varscan2
- TIAM1 | c.3883G>T p.V1295F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54536619; called by muse, mutect2, varscan2
- TMEM131L | c.4550C>G p.S1517C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs201480266, COSV53640628, COSV53650927; called by muse, mutect2, varscan2
- TMEM132B | c.2901G>C p.E967D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV54743936; called by muse, mutect2, varscan2
- TMOD2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51042675; called by muse, mutect2, varscan2
- TNIP1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59303518; called by muse, mutect2
- TNN | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.182); catalogued as rs147066934, COSV53421267; called by muse, mutect2, varscan2
- TRIM22 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV66090089, COSV66091865; called by muse, mutect2, varscan2
- TTN | c.86760C>G p.F28920L (on ENST00000591111; = p.F21496L on NM_003319.4) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | PolyPhen benign (0.006); catalogued as COSV59874193; called by muse, mutect2, varscan2
- TTN | c.24847T>A p.F8283I (on ENST00000591111; = p.F7356I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | PolyPhen possibly damaging (0.747); catalogued as COSV59874231; called by muse, mutect2, varscan2
- UBAP2L | c.2638G>T p.A880S | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.464); catalogued as COSV55167487; called by muse, mutect2, varscan2
- UBIAD1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV65147483; called by muse, mutect2, varscan2
- UNC79 | c.3388C>A p.L1130I (on ENST00000393151 / NM_001346218.2; = p.L953I on NM_020818.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV56372697; called by muse, varscan2
- USH2A | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 107/158 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56324736; called by muse, mutect2, varscan2
- VPS37A | c.519A>T p.L173F | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.7); PolyPhen benign (0.118); catalogued as rs973925469, COSV61352484; called by muse, mutect2, varscan2
- VWA3A | c.3071T>C p.M1024T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55387727; called by muse, mutect2, varscan2
- WDR37 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54126648; called by muse, mutect2, varscan2
- XYLT1 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV54476582; called by muse, mutect2, varscan2
- ZBTB40 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768127997, COSV65144539; called by mutect2, varscan2
- ZCCHC13 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV100272447, COSV59865941; called by muse, mutect2, varscan2
- ZFHX4 | c.2741C>T p.S914F | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV50481780, COSV50775086; called by muse, mutect2, varscan2
- ZFX | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58446451; called by muse, mutect2, varscan2
- ZNF257 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV71306197; called by muse, mutect2, varscan2
- ZNF35 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV56075804; called by muse, mutect2, varscan2
- ZNF367 | c.495C>A p.S165R | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64546553; called by muse, mutect2, varscan2
- ZNF423 | c.2884G>T p.G962C (on ENST00000563137 / NM_001379286.1; = p.G954C on NM_015069.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52176058; called by muse, mutect2, varscan2
- ZNF44 | c.1415A>G p.K472R (on ENST00000356109 / NM_001164276.2; = p.K424R on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61134602; called by muse, mutect2, varscan2
- ZNF480 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV57994461; called by muse, mutect2, varscan2
- ZNF700 | c.2210G>A p.C737Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54310657; called by muse, mutect2, varscan2
- ZNF74 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1209539068, COSV62620078; called by muse, mutect2, varscan2
- ZNF813 | c.78C>G p.D26E | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV67175621; called by muse, mutect2
- ZP4 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV63910790; called by muse, mutect2, varscan2
- ADNP2 | c.2381_2385del p.L794Qfs*9 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | called by mutect2, pindel, varscan2
- CSMD3 | c.2677_2677+1del p.X893_splice (on ENST00000297405 / NM_001363185.1; = p.X789_splice on NM_052900.3) | Splice Site (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- GAS2 | c.275del p.P92Rfs*2 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- MOGAT3 | c.623_631delinsG p.T208Rfs*26 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | called by pindel, varscan2*
- MSH4 | c.1898del p.S633Lfs*12 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- MTMR3 | c.703_712del p.C235Qfs*20 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- NEB | c.6292_6314del p.S2098Lfs*2 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | called by mutect2, pindel, varscan2
- POU3F4 | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- POU3F4 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SYNRG | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF1L | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- TAF4 | c.2133del p.T712Pfs*2 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- TRBC2 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- WDR72 | c.2555G>T p.G852V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- WDR72 | c.2554G>T p.G852* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- ZIC4 | c.299del p.G100Afs*2 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- ADH4 | c.933A>G p.P311= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV55500025; called by muse, mutect2, varscan2
- AKT2 | c.423C>T p.S141= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as COSV60907519; called by muse, mutect2, varscan2
- ATP13A4 | c.2919C>G p.L973= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV61315979; called by muse, mutect2, varscan2
- BDP1 | c.1464G>C p.A488= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV62428692; called by muse, mutect2, varscan2
- BICC1 | c.429A>G p.E143= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs769695375, COSV65855885; called by muse, mutect2, varscan2
- BOD1 | c.516C>T p.P172= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs769176350, COSV53632348; called by muse, mutect2
- C1orf43 | c.48G>A p.V16= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV55167478; called by muse, mutect2, varscan2
- C3 | c.2871G>T p.V957= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV55568268; called by muse, mutect2, varscan2
- CACNG3 | c.132T>A p.S44= | Silent (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- CCDC51 | c.870G>A p.P290= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1417976332, COSV56486516; called by muse, mutect2, varscan2
- COL17A1 | c.4459C>A p.R1487= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV59823546; called by muse, mutect2, varscan2
- DIS3 | c.1677A>G p.A559= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV66705527; called by muse, mutect2, varscan2
- DSC3 | c.231G>A p.G77= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100844754, COSV64571555; called by muse, mutect2, varscan2
- DYNC1H1 | c.4776G>C p.L1592= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV64134179; called by muse, mutect2, varscan2
- FBXL12 | c.909G>T p.L303= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV56113587; called by muse, mutect2, varscan2
- FOXR1 | c.828C>A p.I276= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV57651195; called by muse, mutect2, varscan2
- GADD45G | c.303G>T p.L101= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52999662; called by muse, varscan2
- GPHB5 | c.42C>T p.L14= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100030255, COSV58485479; called by muse, mutect2, varscan2
- MARCO | c.414T>A p.T138= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100503913; called by muse, mutect2, varscan2
- MFHAS1 | c.1654C>T p.L552= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52279764; called by muse, mutect2, varscan2
- MLNR | c.720G>A p.A240= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV54531556; called by muse, varscan2
- MMP13 | c.1386C>A p.V462= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as COSV52822993; called by muse, mutect2, varscan2
- MTA3 | c.735C>T p.S245= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV65921995; called by muse, mutect2, varscan2
- MTOR | c.1713G>T p.T571= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV63868197; called by muse, mutect2, varscan2
- OR2G6 | c.726G>T p.S242= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV58573606, COSV58575678; called by muse, mutect2, varscan2
- OR9A4 | c.696T>G p.S232= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV71884943; called by muse, mutect2, varscan2
- OTUD5 | c.1366C>A p.R456= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV50233804, COSV50240660, COSV99331981; called by muse, mutect2, varscan2
- PCDHB7 | c.849C>T p.Y283= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV50753492; called by muse, mutect2, varscan2
- PITPNM3 | c.789C>T p.I263= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs554495556, COSV52592801; called by muse, mutect2, varscan2
- PLD3 | c.1413T>G p.P471= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as COSV52518959; called by muse, mutect2, varscan2
- PNPLA4 | c.315G>A p.E105= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs750679693, COSV66853695; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1350C>T p.F450= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV53450705; called by muse, mutect2, varscan2
- PRR35 | c.240C>T p.S80= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs975010783, COSV53461838; called by muse, mutect2
- PTGER3 | c.318C>T p.T106= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1315509068, COSV60687372; called by muse, mutect2
- PTPRD | c.1299C>T p.T433= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs759683450, COSV61926637; called by muse, mutect2, varscan2
- REG3G | c.147C>A p.S49= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV55447812; called by muse, varscan2
- RGS12 | c.1689C>T p.G563= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV60901974; called by muse, mutect2, varscan2
- RPS6KC1 | c.1542A>G p.T514= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV65296930; called by muse, mutect2, varscan2
- SLC2A9 | c.1083G>T p.G361= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1432915400, COSV53316233; called by muse, mutect2, varscan2
- SLIT2 | c.576G>T p.V192= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV56559152, COSV56568909; called by muse, mutect2, varscan2
- SPA17 | c.455G>A p.*152= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV57031781; called by muse, mutect2, varscan2
- TECRL | c.480C>A p.L160= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- TENM4 | c.3213C>T p.Y1071= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV53606219; called by muse, mutect2, varscan2
- TIAM1 | c.414C>T p.D138= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs765881295, COSV54536633; called by muse, mutect2, varscan2
- TLL1 | c.2430C>T p.H810= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV50261427; called by muse, mutect2, varscan2
- TNXB | c.6864C>T p.T2288= (on ENST00000647633; = p.T2041= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs773758421, COSV64472853; called by muse, mutect2, varscan2
- TOGARAM1 | c.3747A>G p.L1249= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV63890380; called by muse, mutect2, varscan2
- TOR1A | c.963G>T p.T321= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV52212205; called by muse, mutect2, varscan2
- TOX2 | c.1017G>T p.T339= (on ENST00000358131 / NM_001098798.2; = p.T315= on NM_032883.3) | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV57882013; called by muse, mutect2, varscan2
- TPP2 | c.1980A>T p.R660= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV65750849; called by muse, mutect2
- VAPB | c.547C>T p.L183= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs374376908; called by muse, mutect2
- ZNF501 | c.66A>G p.S22= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV68516123; called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1859G>T | Intron (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2
- EI24P4 | n.889C>A | RNA (SNP) | VAF 99/220 reads (45%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5077G>T | Intron (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- PML | c.1710+1371G>A | Intron (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- TMEM107 | c.*695G>A | 3'UTR (SNP) | VAF 13/38 reads (34%) | catalogued as rs772667974, COSV100328667; called by muse, mutect2, varscan2
- ZNF99 | c.4-656G>C | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as COSV68054647; called by muse, mutect2, varscan2
